Somatic mutation profile of tumor specimen TCGA-86-A4JF-01A (aliquot TCGA-86-A4JF-01A-11D-A24P-08) from TCGA case TCGA-86-A4JF, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.1 years (20,491 days).
Specimen TCGA-86-A4JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e2a3e4-854b-414d-8f1f-2d3682a4e897.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-A4JF-10A (Blood Derived Normal), aliquot TCGA-86-A4JF-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/376e0df4-6287-4ef6-8af5-f7f4f0285e1c

The open-access MAF lists 1,468 somatic variants for this specimen: 1,097 protein-altering or splice-affecting, 340 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 879, Silent 340, Frame Shift Del 95, Nonsense Mutation 51, Frame Shift Ins 34, Splice Site 18, Intron 14, In Frame Del 11, Splice Region 9, RNA 8, 3'UTR 6, 3'Flank 2.

Variants (750 of 1,468; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HGD | c.970dup p.V324Gfs*3 | Frame Shift Ins (INS) | VAF 17/139 reads (12%) | catalogued as rs34214309; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 16/62 reads (26%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A1BG | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV99568687; called by muse, mutect2
- A2ML1 | c.3001C>T p.R1001W | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs201725377, CM157817, COSV100229500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AADACL2 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100735837, COSV62931685; called by muse, mutect2, varscan2
- ABCA13 | c.7537A>T p.R2513* | Nonsense Mutation (SNP) | VAF 46/290 reads (16%) | catalogued as COSV101447226; called by muse, mutect2, varscan2
- ABCB4 | c.1598T>A p.L533Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99711313; called by muse, mutect2, varscan2
- ABCC3 | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs763668442, COSV99559851; called by muse, mutect2, varscan2
- ABHD11 | c.288+2T>C p.X96_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99766943; called by muse, mutect2, varscan2
- ABI3BP | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); catalogued as rs1287946432, COSV99428617; called by muse, mutect2, varscan2
- AC024598.1 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100760490; called by muse, mutect2
- ACACB | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100623309; called by muse, mutect2, varscan2
- ACAN | c.4739C>A p.A1580D | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV100719323, COSV61363425; called by muse, mutect2, varscan2
- ACER1 | c.790T>C p.C264R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100034133; called by muse, mutect2, varscan2
- ACIN1 | c.3004G>T p.V1002L | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.621); catalogued as COSV99400358; called by muse, mutect2, varscan2
- ACIN1 | c.3003G>T p.Q1001H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV99400360; called by muse, mutect2, varscan2
- ACSL1 | c.1619A>G p.D540G | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99860978; called by muse, mutect2, varscan2
- ACSM2A | c.1010T>G p.V337G (on ENST00000219054; = p.V258G on NM_001308169.2) | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs4586421, COSV99525727; called by muse, mutect2, varscan2
- ACTG1 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV100112065, COSV59511151; called by muse, mutect2, varscan2
- ACTL6A | c.269del p.N90Mfs*47 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs1560010257; called by mutect2, pindel, varscan2
- ACTL6B | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV50517369; called by muse, mutect2, varscan2
- ACTL6B | c.563-1G>T p.X188_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99355769; called by muse, mutect2, varscan2
- ACTR1A | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs774729899, COSV64024302; called by muse, mutect2, varscan2
- ADAM19 | c.353C>G p.T118R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as COSV57435158, COSV99978504; called by muse, mutect2
- ADAMTS12 | c.2294A>G p.Y765C | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61283979; called by muse, mutect2, varscan2
- ADAMTS16 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); catalogued as COSV99943050; called by muse, mutect2, varscan2
- ADAMTS3 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99712082; called by mutect2, varscan2
- ADCY4 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs750000650, COSV60251740; called by muse, mutect2, varscan2
- ADGRE5 | c.880G>A p.A294T (on ENST00000242786 / NM_078481.4; = p.A201T on NM_001784.5) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1568314401, COSV99663284; called by muse, mutect2, varscan2
- ADGRL2 | c.3404G>C p.R1135P (on ENST00000370717 / NM_001366005.1; = p.R1122P on NM_012302.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54680274, COSV99591631; called by muse, mutect2, varscan2
- ADIPOR1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100579671; called by muse, mutect2, varscan2
- ADNP2 | c.3140A>G p.E1047G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100081221; called by muse, mutect2, varscan2
- ADPRH | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100813371; called by muse, mutect2, varscan2
- ADRA1D | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760506161, COSV101063152; called by mutect2, varscan2
- AGL | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV54052678; called by muse, mutect2, varscan2
- AGL | c.4334A>T p.Y1445F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99650061; called by muse, mutect2, varscan2
- AGO4 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100943093; called by muse, mutect2
- AHNAK | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as COSV99949673; called by muse, mutect2, varscan2
- AKAP10 | c.1038A>G p.I346M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs778214457, COSV56730789; called by muse, mutect2, varscan2
- AKNAD1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100645882; called by muse, mutect2, varscan2
- AL592490.1 | c.2840A>T p.D947V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV101308287; called by muse, mutect2, varscan2
- ALG10 | c.477del p.F159Lfs*7 | Frame Shift Del (DEL) | VAF 36/215 reads (17%) | catalogued as rs1209514645; called by mutect2, pindel, varscan2
- AMDHD1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs1273349590, COSV57140655, COSV99900529; called by muse, mutect2, varscan2
- ANAPC5 | c.1976A>G p.D659G | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99946491; called by muse, mutect2
- ANAPC5 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99946497; called by muse, mutect2, varscan2
- ANGPTL2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1393923800, COSV52220529, COSV52228085; called by mutect2, varscan2
- ANGPTL2 | c.50T>C p.M17T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV99402606; called by muse, mutect2, varscan2
- ANK2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.567); catalogued as rs761620495, COSV100001977, COSV52146896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD27 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs146675026, COSV60134167; called by muse, mutect2, varscan2
- ANKS1B | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100248054; called by muse, mutect2, varscan2
- ANLN | c.1955G>C p.R652P | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV99732896; called by muse, mutect2, varscan2
- ANO7 | c.805G>A p.G269S (on ENST00000274979; = p.G215S on NM_001370694.2) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51476559, COSV99239480; called by muse, mutect2
- ANP32A | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.011); catalogued as COSV51189538; called by muse, mutect2, varscan2
- AP2A2 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV100173354; called by muse, mutect2, varscan2
- AP3M2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1479411726, COSV99441922; called by muse, mutect2, varscan2
- APMAP | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV54177243; called by muse, mutect2, varscan2
- APOL5 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV99968473; called by muse, mutect2, varscan2
- AQP8 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99564200; called by muse, mutect2, varscan2
- ARHGAP20 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99505395; called by muse, mutect2, varscan2
- ARHGAP32 | c.3616C>T p.R1206C (on ENST00000310343 / NM_001378025.1; = p.R857C on NM_014715.4) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs200179924, COSV59847056; called by muse, mutect2, varscan2
- ARHGAP44 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs1164451727, COSV52390496; called by muse, mutect2, varscan2
- ARHGEF10 | c.1199A>T p.D400V (on ENST00000398564; = p.D375V on NM_014629.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV100035648; called by muse, mutect2, varscan2
- ARHGEF17 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV55239947, COSV99735012; called by muse, mutect2, varscan2
- ARL6IP1 | c.577_580del p.K193Ffs*37 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs879255572; called by pindel, varscan2
- ARMC5 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99192593; called by muse, mutect2, varscan2
- ARNTL | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724891; called by muse, mutect2, varscan2
- ARNTL2 | c.1885T>C p.F629L | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as COSV99668095; called by muse, mutect2, varscan2
- ARRB2 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV99347284; called by muse, mutect2, varscan2
- ARRB2 | c.1197G>A p.M399I | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99347286; called by muse, mutect2, varscan2
- ARV1 | c.272T>G p.I91S | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100048617; called by muse, mutect2, varscan2
- ASCC3 | c.5959G>C p.A1987P | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100976926; called by muse, mutect2, varscan2
- ASTN1 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV99923111; called by muse, mutect2, varscan2
- ASTN2 | c.2111C>A p.S704Y (on ENST00000313400 / NM_001365069.1; = p.S653Y on NM_014010.5) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100530378; called by muse, mutect2, varscan2
- ASTN2 | c.1115C>A p.P372Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.106); catalogued as rs534797977, COSV100530379; called by muse, mutect2, varscan2
- ASXL2 | c.3202C>T p.Q1068* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV99712033; called by muse, mutect2, varscan2
- ASXL3 | c.6530T>A p.I2177N | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99326646; called by muse, mutect2, varscan2
- ATG2B | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV100738274; called by muse, mutect2, varscan2
- ATG9A | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99522278; called by muse, mutect2, varscan2
- ATP10B | c.3603T>A p.D1201E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100515781; called by muse, mutect2, varscan2
- ATP13A5 | c.1754G>T p.S585I | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1274599134, COSV100665738; called by muse, mutect2, varscan2
- ATP1A1 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV55192059; called by muse, mutect2, varscan2
- ATP1A3 | c.871A>T p.I291F (on ENST00000545399 / NM_001256214.2; = p.I278F on NM_152296.5) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100132552; called by muse, varscan2
- ATP1A3 | c.812G>T p.G271V (on ENST00000545399 / NM_001256214.2; = p.G258V on NM_152296.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132554; called by muse, varscan2
- ATP8B4 | c.2923G>T p.G975W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.159); catalogued as COSV99467555; called by muse, mutect2, varscan2
- ATP9A | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262326228, COSV100125645; called by mutect2, varscan2
- AXIN1 | c.403_405del p.E135del | In Frame Del (DEL) | VAF 24/122 reads (20%) | catalogued as rs1225958459; called by pindel, varscan2
- B3GALNT2 | c.1489T>A p.C497S | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100782884; called by muse, mutect2, varscan2
- B4GALNT3 | c.1874T>C p.V625A | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99843619; called by muse, mutect2
- BACH1 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs1044331216, COSV99728721; called by muse, mutect2
- BCAS3 | c.1912A>C p.I638L (on ENST00000390652 / NM_001353144.2; = p.I623L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV101177142; called by muse, mutect2, varscan2
- BCL2L13 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100456418; called by muse, mutect2
- BEND3 | c.1349T>A p.I450N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100944689; called by muse, mutect2, varscan2
- BEND3 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100944690; called by muse, mutect2, varscan2
- BEND6 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); catalogued as COSV100876970; called by muse, mutect2, varscan2
- BICDL1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs762911693, COSV99984716; called by muse, mutect2, varscan2
- BICRAL | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs568633954, COSV100017812; called by muse, mutect2, varscan2
- BIRC7 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99417005; called by muse, mutect2, varscan2
- BMX | c.752+2T>C p.X251_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100564678; called by muse, mutect2
- BPNT1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100435856; called by muse, mutect2
- BPTF | c.3451G>C p.E1151Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100075117; called by muse, mutect2, varscan2
- BPTF | c.4074G>C p.K1358N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as COSV100076059, COSV100076176; called by muse, mutect2, varscan2
- BPTF | c.8621C>T p.T2874M | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781919328, COSV100076065; called by muse, mutect2
- BRCA2 | c.6785T>C p.M2262T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as CM162744, COSV101204661; called by muse, mutect2
- BRD1 | c.1474dup p.L492Pfs*21 | Frame Shift Ins (INS) | VAF 10/67 reads (15%) | catalogued as rs1232261297; called by mutect2, pindel, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 10/45 reads (22%) | catalogued as rs749043197; called by mutect2, varscan2
- BTBD6 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1258400198, COSV59270979; called by muse, mutect2, varscan2
- BTNL8 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 53/260 reads (20%) | catalogued as rs937173927, COSV99180586; called by muse, mutect2, varscan2
- BZW2 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99334895; called by muse, mutect2, varscan2
- C12orf40 | c.991T>C p.C331R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.387); catalogued as COSV100210790; called by muse, mutect2, varscan2
- C1S | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as rs782488121, COSV61072306; called by muse, mutect2, varscan2
- C2orf16 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV101284427; called by muse, mutect2
- C2orf16 | c.4609A>G p.K1537E | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100821031; called by muse, mutect2, varscan2
- C6 | c.1783del p.Q595Nfs*36 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | catalogued as rs767886734; called by mutect2, pindel, varscan2
- C7 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as COSV100496622; called by muse, mutect2
- C8orf82 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV99432283; called by muse, mutect2, varscan2
- CA9 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.035); catalogued as rs1336562008, COSV100999904; called by muse, mutect2, varscan2
- CA9 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100999906, COSV65676345; called by muse, mutect2, varscan2
- CACNA1E | c.1121A>G p.Q374R | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100705398; called by muse, mutect2
- CACNA1E | c.4511G>A p.C1504Y | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100705405; called by muse, mutect2
- CACNA1E | c.6368G>T p.S2123I (on ENST00000367573 / NM_001205293.3; = p.S2080I on NM_000721.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100705408; called by muse, mutect2, varscan2
- CACNA1H | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs754161411, COSV62009280; called by muse, varscan2
- CACNA1H | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1047764685, COSV100673523; called by muse, varscan2
- CALD1 | c.2027A>G p.D676G (on ENST00000361675 / NM_033138.4; = p.D421G on NM_004342.7) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); catalogued as COSV100724587; called by muse, mutect2
- CARD18 | c.114A>T p.E38D | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101596039; called by muse, mutect2, varscan2
- CASKIN1 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); catalogued as COSV100624438, COSV58874935; called by muse, varscan2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs1247046723, COSV61881818; called by mutect2, pindel
- CASS4 | c.1172C>A p.P391Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100824929; called by muse, mutect2, varscan2
- CASS4 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs770375718, COSV100824930; called by muse, mutect2, varscan2
- CBWD2 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV99380831; called by muse, mutect2, varscan2
- CCDC110 | c.2498A>G p.H833R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100294191; called by muse, mutect2, varscan2
- CCDC116 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374196676; called by muse, mutect2
- CCDC178 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); catalogued as COSV100286827, COSV55775232; called by muse, mutect2, varscan2
- CCDC40 | c.2734A>T p.K912* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100884327; called by muse, mutect2, varscan2
- CCDC7 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100179306, COSV56542497; called by muse, mutect2, varscan2
- CCER1 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as COSV100727166; called by muse, varscan2
- CCN4 | c.349+1G>A p.X117_splice | Splice Site (SNP) | VAF 8/83 reads (10%) | catalogued as rs755069138, COSV99137428; called by muse, mutect2, varscan2
- CD163L1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100550681, COSV58026549; called by muse, mutect2, varscan2
- CD209 | c.1091G>C p.W364S | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52655534, COSV99214446; called by muse, mutect2, varscan2
- CD300A | c.378G>T p.P126= | Splice Region (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100177992; called by muse, mutect2, varscan2
- CD300LF | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs760947857, COSV100042888; called by muse, mutect2, varscan2
- CD44 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99556018; called by muse, mutect2
- CD48 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs7556485, COSV100924268, COSV100924304; called by muse, varscan2
- CD72 | c.161T>C p.L54S | Missense Mutation (SNP) | VAF 79/381 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV99427627; called by muse, mutect2, varscan2
- CDAN1 | c.2533G>A p.G845R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.862); catalogued as rs1439511041, COSV100661449; called by muse, mutect2, varscan2
- CDCP2 | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100313694; called by muse, mutect2, varscan2
- CDH19 | c.1579A>G p.N527D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100052376; called by muse, mutect2, varscan2
- CDH20 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.909); catalogued as COSV53011666, COSV99406569; called by muse, mutect2
- CDH24 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99943856; called by muse, mutect2
- CDH26 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs184110890, COSV99722330; called by muse, mutect2, varscan2
- CDH7 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.057); catalogued as COSV100543270; called by muse, mutect2, varscan2
- CDH8 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs772878546, COSV54867033; called by muse, mutect2, varscan2
- CDHR3 | c.2129G>T p.W710L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1019025057, COSV100488879; called by muse, mutect2, varscan2
- CDK16 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52092673; called by muse, mutect2, varscan2
- CDKL5 | c.1643A>G p.N548S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.006); catalogued as COSV101184460; called by muse, mutect2, varscan2
- CDKN1B | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as COSV57431863; called by muse, mutect2, varscan2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | catalogued as rs773511514; called by mutect2, varscan2
- CELSR3 | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99375043; called by muse, mutect2, varscan2
- CEMIP | c.3646G>C p.E1216Q | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.543); catalogued as COSV99587308; called by muse, mutect2
- CEP170 | c.2060A>G p.Y687C | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.294); catalogued as rs1475694296, COSV100317913; called by muse, mutect2, varscan2
- CEP44 | c.969A>C p.K323N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99639812; called by muse, mutect2
- CEP57L1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs570190412, COSV100425978; called by muse, mutect2, varscan2
- CEP89 | c.1649_1651del p.K550del | In Frame Del (DEL) | VAF 30/168 reads (18%) | catalogued as rs776318262; called by pindel, varscan2
- CETN1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59122220; called by muse, mutect2, varscan2
- CFAP43 | c.3962C>T p.T1321M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs1454679391, COSV100829479; called by muse, mutect2, varscan2
- CFAP47 | c.1391T>C p.I464T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99935860; called by muse, mutect2, varscan2
- CFAP54 | c.7663G>A p.A2555T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100733344; called by muse, mutect2, varscan2
- CFAP61 | c.1055C>A p.T352N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99846686; called by muse, mutect2, varscan2
- CFAP70 | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100161083; called by muse, mutect2
- CFHR3 | c.856A>C p.S286R | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100807793; called by muse, mutect2, varscan2
- CFHR4 | c.1246G>A p.D416N (on ENST00000367416 / NM_001201551.2; = p.D170N on NM_006684.5) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99261399; called by muse, mutect2, varscan2
- CGRRF1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99370595; called by muse, mutect2, varscan2
- CHAF1A | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768790348, COSV100011486; called by muse, mutect2, varscan2
- CHAT | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769204680, COSV60333235; called by muse, mutect2, varscan2
- CHCHD6 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337053; called by muse, mutect2, varscan2
- CHD3 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391720, COSV57878997; called by mutect2, varscan2
- CHRM3 | c.1750C>A p.R584S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV55090620, COSV99699501; called by muse, mutect2, varscan2
- CHRNA4 | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100937486; called by muse, mutect2, varscan2
- CHRNA6 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs199691486, COSV99373425; called by muse, mutect2, varscan2
- CHRNA9 | c.851T>A p.L284Q | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100039136; called by muse, mutect2, varscan2
- CHRNB3 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs185338940; called by muse, mutect2, varscan2
- CILP2 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52281610; called by muse, mutect2, varscan2
- CLCN3 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV100641835; called by muse, mutect2, varscan2
- CLDN4 | c.185T>C p.M62T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99936612; called by muse, mutect2, varscan2
- CLSPN | c.3093T>A p.D1031E | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV99231540; called by muse, mutect2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | catalogued as rs751921758; called by pindel, varscan2
- CNOT2 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57501995, COSV99973149; called by muse, mutect2, varscan2
- CNR1 | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV100759353; called by muse, mutect2, varscan2
- CNTLN | c.1988-1G>C p.X663_splice | Splice Site (SNP) | VAF 20/120 reads (17%) | catalogued as COSV99265731; called by muse, mutect2, varscan2
- CNTNAP1 | c.2215T>C p.W739R | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV99227035; called by muse, mutect2, varscan2
- CNTNAP2 | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1294234578, COSV100673042; called by muse, mutect2, varscan2
- COG8 | c.1583G>A p.G528D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1380706136, COSV55340615; called by mutect2, varscan2
- COL11A2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs764076227, COSV100554553; called by muse, mutect2, varscan2
- COL24A1 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1372770570, COSV100994003; called by muse, mutect2
- COL3A1 | c.3596G>T p.G1199V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100483745; called by muse, mutect2, varscan2
- COL4A2 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1305493217, COSV100847490; called by muse, mutect2
- COL4A2 | c.4229G>A p.R1410Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs1004346642, COSV64629756; called by muse, mutect2
- COL4A3 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101170174; called by muse, mutect2, varscan2
- COL4A3 | c.3886G>T p.A1296S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV101170538; called by muse, mutect2, varscan2
- COL5A2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs545574407, COSV66415414, COSV66415595; ClinVar: uncertain significance; called by muse, mutect2
- COL6A6 | c.4619G>C p.G1540A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62023629; called by muse, mutect2, varscan2
- COL9A1 | c.1767T>C p.G589= | Splice Region (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100295641; called by muse, mutect2
- COL9A1 | c.802-2A>T p.X268_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100295646; called by muse, mutect2, varscan2
- COPRS | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 94/520 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs762134733, COSV55574481, COSV99912151; called by muse, mutect2, varscan2
- COQ5 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202246526, COSV99942528; called by muse, mutect2, varscan2
- COQ9 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs748239782, COSV52646559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPED1 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as COSV100121508; called by muse, mutect2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 14/98 reads (14%) | catalogued as rs777945397; called by mutect2, varscan2
- CPXM1 | c.1927A>G p.I643V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV101013840; called by muse, mutect2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV51715473; called by mutect2, pindel
- CREBBP | c.1589A>T p.N530I | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV52135723, COSV99272101; called by muse, mutect2
- CRMP1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs548835481, COSV100271702; called by muse, mutect2, varscan2
- CRX | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs146869548; called by muse, mutect2, varscan2
- CSDE1 | c.1762A>G p.I588V (on ENST00000358528 / NM_001007553.3; = p.I557V on NM_007158.6) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs751189072, COSV99796028; called by muse, mutect2, varscan2
- CSE1L | c.2697T>A p.Y899* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99522275; called by muse, mutect2, varscan2
- CSMD3 | c.10402G>C p.A3468P (on ENST00000297405 / NM_001363185.1; = p.A3299P on NM_052900.3) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.361); catalogued as COSV99848017, COSV99848047; called by muse, mutect2, varscan2
- CSNK1A1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99939826; called by muse, mutect2, varscan2
- CSNK2A1 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV99424726; called by muse, mutect2, varscan2
- CTDP1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773944371, COSV99311122; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNND2 | c.1965G>T p.E655D | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100481156; called by muse, mutect2, varscan2
- CTRL | c.57C>A p.C19* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99345023; called by muse, mutect2
- CTTNBP2 | c.1039A>C p.T347P | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99354889; called by muse, mutect2, varscan2
- CUBN | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs376195863; called by muse, mutect2, varscan2
- CUEDC1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs564595554, COSV64227184; called by muse, mutect2, varscan2
- CX3CR1 | c.933C>A p.C311* | Nonsense Mutation (SNP) | VAF 38/150 reads (25%) | catalogued as COSV100843291; called by muse, mutect2, varscan2
- CXXC1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53276489; called by muse, mutect2, varscan2
- CYP1A1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs201174966, COSV65697096; called by muse, mutect2
- CYP24A1 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV99398611; called by muse, mutect2, varscan2
- CYP26B1 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV99135048; called by muse, mutect2, varscan2
- CYP2A13 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100387027; called by muse, mutect2, varscan2
- CYP4F11 | c.525+2T>C p.X175_splice | Splice Site (SNP) | VAF 11/85 reads (13%) | catalogued as COSV99931123; called by muse, mutect2, varscan2
- DCST1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.053); catalogued as COSV99793663; called by muse, mutect2
- DCTN1 | c.2763T>G p.P921= | Splice Region (SNP) | VAF 11/122 reads (9%) | catalogued as COSV100721097; called by muse, mutect2
- DDC | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100779751; called by muse, mutect2, varscan2
- DECR2 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557095, COSV99557308; called by muse, mutect2, varscan2
- DENND2C | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs372971179; called by muse, mutect2, varscan2
- DEPDC5 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.674); catalogued as rs1160535755, COSV99836609; called by muse, mutect2
- DEPTOR | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99639411; called by muse, mutect2, varscan2
- DHRS12 | c.510G>A p.V170= (on ENST00000444610 / NM_001377930.1; = p.V121= on NM_024705.2 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99523996; called by muse, mutect2
- DHX16 | c.2186T>C p.V729A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99528195; called by muse, mutect2, varscan2
- DHX34 | c.3236C>T p.T1079M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538434908, COSV60896664; called by muse, mutect2, varscan2
- DHX36 | c.2558A>G p.K853R | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV100273969; called by muse, mutect2, varscan2
- DHX37 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100439518, COSV58131501; called by muse, mutect2, varscan2
- DHX9 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100841526; called by muse, mutect2, varscan2
- DIDO1 | c.5486C>T p.S1829F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99827184; called by muse, mutect2
- DIP2A | c.4666G>A p.G1556S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.172); catalogued as rs369212003; called by muse, mutect2, varscan2
- DIRAS2 | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV101005911; called by muse, mutect2
- DISP2 | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs1045098882, COSV51116484; called by muse, mutect2, varscan2
- DMBT1 | c.6176G>A p.G2059E (on ENST00000338354 / NM_001377530.1; = p.G1302E on NM_004406.3) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100354126; called by muse, mutect2
- DNAAF5 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs1411441157, COSV99860321; called by muse, mutect2, varscan2
- DNAH17 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101103499; called by muse, mutect2, varscan2
- DNAH3 | c.5400G>T p.W1800C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54526053, COSV99770713; called by muse, mutect2, varscan2
- DNAH5 | c.6050G>A p.R2017Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775577387, COSV54240271; called by muse, mutect2, varscan2
- DNAH7 | c.5469del p.F1823Lfs*11 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as COSV56788088; called by mutect2, pindel, varscan2
- DNAH8 | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100547256; called by muse, mutect2, varscan2
- DNM1L | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs764915133, COSV99846460; called by muse, mutect2, varscan2
- DNMBP | c.4659G>C p.E1553D | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.779); catalogued as COSV100144450; called by muse, mutect2, varscan2
- DOC2A | c.191del p.P64Lfs*27 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs753153258; called by mutect2, pindel, varscan2
- DOT1L | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.046); catalogued as COSV101288826; called by muse, mutect2, varscan2
- DOT1L | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.012); catalogued as rs759654625, COSV101288828; called by muse, mutect2, varscan2
- DPF2 | c.968A>C p.Q323P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99361968; called by muse, mutect2, varscan2
- DPYSL5 | c.1205T>A p.V402E | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99982812; called by muse, mutect2, varscan2
- DRC1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs748399379, COSV99985745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.5944G>T p.A1982S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.978); catalogued as COSV101261563; called by muse, mutect2, varscan2
- DSG1 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936591; called by muse, mutect2, varscan2
- DSTYK | c.1598C>G p.S533* | Nonsense Mutation (SNP) | VAF 27/273 reads (10%) | catalogued as COSV100904720; called by muse, mutect2, varscan2
- DUS3L | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100288490; called by muse, mutect2, varscan2
- DUS3L | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100288491; called by muse, mutect2, varscan2
- DVL3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs776529678, COSV100493811; called by muse, mutect2, varscan2
- DYNAP | c.619A>G p.T207A (on ENST00000321600; = p.T181A on NM_173629.3) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs370863733; called by muse, mutect2, varscan2
- E2F2 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100674868, COSV62276253; called by muse, mutect2, varscan2
- EARS2 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV101492194; called by muse, mutect2
- EEF1AKNMT | c.2016G>T p.L672F (on ENST00000361735 / NM_015935.5; = p.L586F on NM_014955.3) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100676049; called by muse, mutect2, varscan2
- EEF2 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100500995; called by muse, mutect2, varscan2
- EGF | c.1895G>A p.G632D | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764784391, COSV99491372; called by muse, mutect2, varscan2
- ELMO3 | c.1552G>A p.D518N (on ENST00000652269; = p.D465N on NM_024712.5) | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs201129653; called by muse, mutect2, varscan2
- ELP5 | c.643C>G p.Q215E | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100598250; called by muse, mutect2, varscan2
- EMILIN1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs774000688, COSV99566555; called by muse, mutect2, varscan2
- EMSY | c.3274G>A p.V1092M | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV100596080; called by muse, varscan2
- EMSY | c.3346G>A p.V1116I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.294); catalogued as rs1302699707, COSV100596082; called by muse, varscan2
- ENO1 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as COSV52302717, COSV99319007; called by muse, mutect2, varscan2
- ENTPD2 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100445919; called by muse, mutect2, varscan2
- ENY2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs754316009, COSV53460886; called by muse, mutect2, varscan2
- EP400 | c.5290G>A p.A1764T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs762411255, COSV100202316, COSV57769119; called by muse, mutect2, varscan2
- EPHA5 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs1331509406, COSV99901321; called by muse, mutect2, varscan2
- EPOR | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV99710318; called by muse, mutect2, varscan2
- EPRS1 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100859510; called by muse, mutect2, varscan2
- ERC1 | c.2387T>C p.L796P (on ENST00000360905 / NM_178040.4; = p.L768P on NM_178039.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100706756; called by muse, mutect2, varscan2
- ERICH6 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV99902015; called by muse, mutect2, varscan2
- ESCO2 | c.801A>T p.E267D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100533418; called by muse, mutect2, varscan2
- ESPL1 | c.6301C>T p.R2101* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99229794; called by muse, mutect2, varscan2
- EVA1B | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54633569; called by muse, varscan2
- F5 | c.568del p.L190Cfs*9 | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | catalogued as COSV100888918; called by mutect2, pindel
- FAAP100 | c.2175C>T p.G725= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as rs758795190, COSV59884544; called by muse, mutect2, varscan2
- FAH | c.1192G>T p.G398W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99930567; called by muse, mutect2, varscan2
- FAM124B | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99706410, COSV99706500; called by muse, mutect2, varscan2
- FAM135A | c.1238A>C p.Y413S (on ENST00000370479 / NM_001351599.1; = p.Y396S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99526678; called by muse, mutect2
- FAM160B1 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100985599; called by muse, mutect2, varscan2
- FAM162A | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs749194849, COSV51658999; called by muse, mutect2, varscan2
- FAM166A | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100458203; called by muse, mutect2, varscan2
- FAM20A | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as rs747920001, COSV99873256, COSV99873315; called by muse, mutect2, varscan2
- FAM78A | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201778288, COSV55992033; called by muse, mutect2, varscan2
- FASLG | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100390670; called by muse, mutect2
- FAT1 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs761076845, COSV101499650; called by muse, mutect2, varscan2
- FAT3 | c.8323A>C p.T2775P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV99971175; called by muse, mutect2, varscan2
- FAT3 | c.8773G>A p.A2925T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.108); catalogued as rs745373906, COSV53085882; called by muse, mutect2, varscan2
- FAT3 | c.9386del p.P3129Lfs*22 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as COSV99962642; called by mutect2, pindel, varscan2
- FBXW2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100535318; called by muse, mutect2, varscan2
- FCN1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs1296171087, COSV65662022; called by muse, mutect2, varscan2
- FCRL1 | c.1002A>G p.I334M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV100839906; called by muse, mutect2, varscan2
- FCRL2 | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100830013; called by muse, mutect2, varscan2
- FCRL3 | c.116A>T p.K39I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV100943562; called by muse, mutect2, varscan2
- FCRL4 | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 7/115 reads (6%) | catalogued as COSV54860005, COSV99620480; called by muse, mutect2
- FCRL5 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.915); catalogued as COSV100709337; called by muse, mutect2, varscan2
- FGF18 | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51126810; called by muse, mutect2, varscan2
- FGF2 | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99144725; called by muse, mutect2, varscan2
- FKBP2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100501854; called by muse, mutect2
- FLG | c.5846A>C p.Q1949P | Missense Mutation (SNP) | VAF 195/897 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100912229; called by muse, mutect2, varscan2
- FLG | c.4708A>G p.S1570G | Missense Mutation (SNP) | VAF 82/578 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100912230; called by muse, mutect2, varscan2
- FLG | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 103/880 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV64238912; called by muse, mutect2, varscan2
- FLII | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as rs774800032, COSV58944206; called by muse, mutect2, varscan2
- FNDC1 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs1190667940, COSV51931872; called by muse, mutect2, varscan2
- FNDC7 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs778671617, COSV54756993; called by muse, mutect2, varscan2
- FOCAD | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100620704; called by muse, mutect2, varscan2
- FOLH1 | c.1585G>T p.G529* | Nonsense Mutation (SNP) | VAF 20/192 reads (10%) | catalogued as COSV99923961; called by muse, mutect2, varscan2
- FOLR3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs1287584454, COSV61529960; called by muse, mutect2, varscan2
- FOXO4 | c.1203dup p.L402Afs*6 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as rs754124740; called by mutect2, varscan2
- FRMD1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765036020, COSV99349550; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRY | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100969938; called by muse, mutect2, varscan2
- FSCN3 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV99757391; called by muse, mutect2, varscan2
- FSTL5 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV100056435, COSV100061310; called by muse, mutect2, varscan2
- FTSJ1 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV99191455; called by muse, mutect2, varscan2
- FZD10 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99969615; called by muse, mutect2
- G6PC3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs374402992, COSV52241995; called by muse, mutect2, varscan2
- GAA | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as rs956263455, COSV100163538; called by muse, mutect2, varscan2
- GABRB2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs769682551, COSV99196662; called by muse, mutect2, varscan2
- GABRB2 | c.841A>G p.T281A | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99196666; called by muse, mutect2, varscan2
- GABRB3 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100161902; called by muse, mutect2, varscan2
- GAL3ST4 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | catalogued as COSV100385648; called by muse, mutect2
- GALNT6 | c.1557dup p.K520Efs*18 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs748677519; called by mutect2, pindel, varscan2
- GAS7 | c.334C>G p.P112A (on ENST00000432992 / NM_201433.2; = p.P52A on NM_201432.2) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100097057, COSV60443842; called by muse, mutect2, varscan2
- GATA2 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV100351557; called by muse, mutect2
- GATB | c.327+2T>C p.X109_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99859344; called by muse, mutect2
- GCC2 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.178); catalogued as COSV100565653; called by muse, mutect2
- GCC2 | c.2627A>G p.Q876R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100565654; called by muse, mutect2, varscan2
- GCNT1 | c.1238G>A p.C413Y | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946657, COSV100946690; called by muse, mutect2
- GGT5 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs1257235419, COSV99571880; called by muse, mutect2, varscan2
- GJC2 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.99); catalogued as COSV100813007; called by muse, mutect2
- GLS | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV100290548; called by muse, mutect2, varscan2
- GLT8D2 | c.127A>T p.T43S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100674250; called by muse, mutect2, varscan2
- GNAQ | c.963C>A p.D321E | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99681995; called by muse, mutect2, varscan2
- GNPTAB | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs376620571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 7/140 reads (5%) | catalogued as COSV101001995; called by muse, mutect2
- GP2 | c.626G>T p.C209F (on ENST00000381362 / NM_001007240.3; = p.C206F on NM_001502.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100221661; called by muse, mutect2, varscan2
- GPR139 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750115024, COSV100430045, COSV58502171; called by muse, mutect2, varscan2
- GPR141 | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as COSV100550471; called by muse, mutect2, varscan2
- GPR158 | c.2771G>A p.G924D | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.11); catalogued as COSV100894310, COSV66281622; called by muse, mutect2
- GPR182 | c.357G>C p.W119C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267801; called by mutect2, varscan2
- GPR68 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs554876233, COSV99473591; called by muse, mutect2
- GRAMD1A | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100526419, COSV58766334; called by muse, mutect2
- GRB14 | c.612dup p.P205Sfs*10 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs780357659; called by mutect2, varscan2
- GRID2 | c.2155G>T p.E719* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV99936851, COSV99947001; called by muse, mutect2, varscan2
- GRIK5 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99491379; called by muse, mutect2
- GRIN3A | c.1688G>T p.S563I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV100701843; called by muse, mutect2, varscan2
- GTPBP2 | c.1101-1G>A p.X367_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100200161; called by muse, mutect2, varscan2
- GUCA1A | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV50004243; called by muse, mutect2
- GUCY1A2 | c.920A>T p.Q307L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56496714; called by muse, mutect2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- GZMK | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99141016; called by muse, mutect2, varscan2
- H2BC7 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.262); catalogued as COSV100587277; called by muse, mutect2, varscan2
- HAS2 | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV100392211, COSV58265389; called by muse, mutect2, varscan2
- HCFC1 | c.2686G>A p.G896R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV60070402, COSV60078682; called by muse, mutect2, varscan2
- HCK | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99394612; called by muse, mutect2, varscan2
- HCN4 | c.2446A>G p.N816D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99984257; called by muse, mutect2, varscan2
- HCRTR2 | c.1043T>C p.F348S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100904344; called by muse, mutect2, varscan2
- HDAC3 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99781534; called by muse, mutect2
- HECTD4 | c.5237C>T p.A1746V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101108382; called by muse, mutect2, varscan2
- HECW1 | c.70T>A p.S24T | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV101224318; called by muse, mutect2, varscan2
- HELZ2 | c.2134G>A p.A712T (on ENST00000467148 / NM_001037335.2; = p.A143T on NM_033405.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100915711; called by muse, mutect2, varscan2
- HERC1 | c.12056T>C p.V4019A | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV101496923; called by muse, mutect2, varscan2
- HERC2 | c.14209C>T p.R4737W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs200909165, COSV99876780; called by muse, mutect2, varscan2
- HIVEP1 | c.5419C>T p.P1807S | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101045761; called by muse, mutect2
- HJURP | c.533C>G p.T178S | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV100982641; called by muse, mutect2, varscan2
- HLX | c.1445A>T p.Q482L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100854627; called by muse, mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs770632206; called by pindel, varscan2
- HRNR | c.7029C>A p.H2343Q | Missense Mutation (SNP) | VAF 170/2832 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1553201540, COSV100913968; called by muse, mutect2
- HSD11B1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99808381; called by muse, mutect2
- HSD17B1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99864942; called by muse, mutect2, varscan2
- HSD17B4 | c.2011G>T p.V671L (on ENST00000414835 / NM_001199291.3; = p.V646L on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV99820175; called by muse, mutect2, varscan2
- HSPA2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as COSV99905152; called by muse, mutect2
- HTR2B | c.1256A>T p.N419I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV99295489; called by muse, mutect2, varscan2
- HUWE1 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99474272; called by muse, varscan2
- IDE | c.150A>G p.I50M | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV99794425; called by muse, mutect2, varscan2
- IFI44 | c.268T>A p.W90R | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.17); catalogued as COSV100877434; called by muse, mutect2
- IFNA13 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs759421265, COSV101489526; called by muse, mutect2, varscan2
- IFT172 | c.4511C>T p.A1504V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1234365830, COSV99561832; called by muse, mutect2, varscan2
- IGFBPL1 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV100890786; called by muse, mutect2, varscan2
- IKBKE | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV100898017, COSV65623247; called by muse, mutect2, varscan2
- IKZF1 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV100498758, COSV58791341; called by muse, mutect2
- IL18RAP | c.1691C>A p.S564Y | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99962423; called by muse, mutect2
- IL21R | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100560600; called by muse, mutect2, varscan2
- IL7R | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV100286689; called by muse, mutect2, varscan2
- ILF2 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100722012; called by muse, mutect2, varscan2
- INPPL1 | c.2140G>A p.V714I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as rs750542712, COSV53356229; called by muse, mutect2, varscan2
- INTS10 | c.1621A>G p.K541E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.297); catalogued as COSV101208746; called by muse, mutect2, varscan2
- INTS3 | c.2380A>G p.N794D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.953); catalogued as COSV99670183; called by muse, mutect2, varscan2
- INVS | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs763460118, COSV99316920; called by mutect2, varscan2
- IPCEF1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs751364357, COSV99500538; called by muse, mutect2, varscan2
- IPO8 | c.2174T>C p.V725A | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99805664; called by muse, mutect2, varscan2
- IQGAP3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as rs373751756, COSV100752385; called by muse, mutect2, varscan2
- ISM2 | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.431); catalogued as COSV99376877; called by muse, mutect2, varscan2
- ITGA10 | c.1517T>A p.V506E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100995053; called by muse, mutect2, varscan2
- ITGA3 | c.2341G>T p.G781C | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99144266; called by muse, mutect2, varscan2
- ITGA8 | c.3105G>T p.K1035N | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100959756; called by muse, mutect2, varscan2
- ITGA8 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760847703, COSV100959234, COSV65236331; called by muse, mutect2, varscan2
- ITGAE | c.2740C>A p.L914I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV99561561; called by muse, mutect2, varscan2
- ITPRID1 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100087552; called by muse, mutect2
- JAG1 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653541; called by muse, mutect2
- JCAD | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100947991, COSV100948577; called by muse, mutect2, varscan2
- JPH1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100646791; called by muse, mutect2
- KANSL1 | c.1396C>A p.Q466K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99294958; called by muse, mutect2, varscan2
- KAZALD1 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930621; called by muse, varscan2
- KBTBD12 | c.1745A>G p.Q582R | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100675532; called by muse, mutect2, varscan2
- KCNA2 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.528); catalogued as rs770338663, COSV60371672; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNC2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV54366177; called by muse, mutect2, varscan2
- KCND2 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100478672; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCNH3 | c.3183G>T p.E1061D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as COSV99235206; called by muse, mutect2, varscan2
- KCNK6 | c.718+1G>A p.X240_splice | Splice Site (SNP) | VAF 15/101 reads (15%) | catalogued as rs753742527, COSV99649493; called by muse, mutect2, varscan2
- KCNQ2 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs780218608, COSV100610565; called by muse, mutect2
- KDM3A | c.2116T>C p.W706R | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100460978; called by muse, mutect2, varscan2
- KDM4B | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs757535110, COSV50220301; called by muse, mutect2, varscan2
- KIAA0319L | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1188136112, COSV57841534; called by muse, mutect2, varscan2
- KIAA0586 | c.2486C>T p.P829L (on ENST00000619416 / NM_001244190.2; = p.P768L on NM_014749.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV99708950; called by muse, mutect2, varscan2
- KIF21A | c.2504G>C p.R835P (on ENST00000361418 / NM_001378440.1; = p.R822P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100735679, COSV62768050; called by muse, mutect2, varscan2
- KIF21A | c.2503C>T p.R835W (on ENST00000361418 / NM_001378440.1; = p.R822W on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1458182449, COSV62777299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2B | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV99276257; called by muse, mutect2, varscan2
- KIR3DL3 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV99400197; called by muse, mutect2
- KIRREL1 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1246209558, COSV100780124; called by muse, mutect2
- KL | c.2489T>A p.V830E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101199135; called by muse, mutect2, varscan2
- KLF10 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.063); catalogued as rs199615401; called by muse, mutect2
- KLHL26 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV99963384; called by muse, mutect2
- KLHL36 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99257117; called by muse, mutect2, varscan2
- KLK5 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.488); catalogued as rs541541684, COSV100307238; called by muse, mutect2, varscan2
- KLRC2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs143264024; called by muse, mutect2
- KNDC1 | c.3952C>T p.R1318W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764482590, COSV58835210; called by muse, mutect2, varscan2
- KRT16 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs140428349, COSV56969933; called by muse, mutect2, varscan2
- KRT24 | c.180del p.F60Lfs*14 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as COSV52881586; called by mutect2, varscan2
- KRT72 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99537504; called by muse, mutect2, varscan2
- KSR2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs779301314, COSV100351269, COSV60374823; called by muse, mutect2, varscan2
- L1TD1 | c.344T>A p.M115K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100776630; called by muse, mutect2, varscan2
- L3MBTL1 | c.1189A>G p.K397E (on ENST00000418998 / NM_001377303.1; = p.K307E on NM_015478.7) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100917062; called by muse, mutect2, varscan2
- LAD1 | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100943957; called by muse, mutect2, varscan2
- LATS2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs745371213, COSV66874492, COSV66877065; called by muse, mutect2, varscan2
- LAX1 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920097; called by muse, mutect2, varscan2
- LCE1C | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100908486; called by muse, mutect2, varscan2
- LCE1E | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100908574; called by muse, mutect2, varscan2
- LCE1F | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV100542787; called by muse, mutect2
- LDHA | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV57042843, COSV99908318; called by muse, mutect2, varscan2
- LDLR | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768925824, COSV52946936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDLRAD4 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100762790; called by muse, mutect2, varscan2
- LENG8 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs964005888, COSV58728700; called by muse, mutect2, varscan2
- LEPR | c.2824C>G p.L942V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV100848420; called by muse, mutect2, varscan2
- LGI2 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV101180946; called by muse, mutect2, varscan2
- LGMN | c.1194C>T p.Y398= | Splice Region (SNP) | VAF 33/186 reads (18%) | catalogued as rs750968260, COSV58402783; called by muse, mutect2, varscan2
- LHX9 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV100436087; called by muse, mutect2, varscan2
- LILRB2 | c.1672del p.Q558Rfs*3 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as rs1569091038; called by mutect2, pindel, varscan2
- LILRB4 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.36); catalogued as rs1279304598, COSV99554120; called by muse, mutect2, varscan2
- LLGL1 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100375673; called by muse, mutect2
- LLGL1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1338497657, COSV100375676; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMAN2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100288513; called by muse, mutect2, varscan2
- LMNB2 | c.1537A>T p.I513F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99296110; called by muse, mutect2, varscan2
- LNPEP | c.1171C>G p.H391D | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99183619; called by muse, mutect2
- LPA | c.2460G>T p.R820S | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as COSV60303679; called by muse, mutect2, varscan2
- LPA | c.2459G>A p.R820K | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.006); catalogued as rs371424052, COSV100306068, COSV100308086; called by muse, mutect2, varscan2
- LPIN3 | c.2494T>C p.Y832H | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100182827; called by muse, mutect2, varscan2
- LRP1B | c.10414G>A p.D3472N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs201825848; called by muse, mutect2, varscan2
- LRRC14 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99468260; called by muse, mutect2, varscan2
- LRRC8A | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV99396948; called by muse, mutect2, varscan2
- LYST | c.11302A>G p.T3768A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.493); catalogued as COSV101090323; called by muse, mutect2
- LZTS1 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV99743332; called by muse, mutect2, varscan2
- LZTS2 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as COSV100932296; called by muse, mutect2, varscan2
- MAGEB4 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100854819; called by muse, mutect2, varscan2
- MAML1 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs376849937, COSV99482938; called by muse, mutect2, varscan2
- MAN2A1 | c.1406A>T p.D469V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV99811936; called by muse, mutect2, varscan2
- MAN2B2 | c.2948C>T p.P983L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV99578100; called by muse, mutect2, varscan2
- MAP1A | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as rs940386263, COSV100289324; called by muse, mutect2, varscan2
- MAP2 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV52291267; called by muse, mutect2, varscan2
- MAP3K19 | c.3775G>C p.E1259Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209327; called by muse, mutect2, varscan2
- MAP3K19 | c.3664G>T p.D1222Y | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100209331; called by muse, mutect2, varscan2
- MAP3K2 | c.1139G>T p.R380I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV61294428; called by muse, mutect2, varscan2
- MAP3K21 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100786169; called by muse, mutect2
- MAP3K5 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100753283; called by muse, mutect2
- MAPK8IP3 | c.2581A>G p.N861D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.198); catalogued as COSV99169781; called by muse, mutect2, varscan2
- MAPT | c.2217G>T p.K739N (on ENST00000262410 / NM_001377265.1; = p.K347N on NM_005910.5) | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV99291361; called by muse, mutect2
- MARS2 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99986704; called by muse, mutect2, varscan2
- MASP1 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1339366002, COSV51457175, COSV99397680; called by muse, mutect2, varscan2
- MAST3 | c.3806T>C p.V1269A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV99446322; called by muse, mutect2
- MATN4 | c.1834G>A p.E612K (on ENST00000372754; = p.E571K on NM_003833.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | PolyPhen benign (0.21); catalogued as COSV100637172; called by muse, mutect2, varscan2
- MATN4 | c.1079A>G p.Y360C (on ENST00000372754; = p.Y319C on NM_003833.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | PolyPhen possibly damaging (0.886); catalogued as COSV100637174; called by muse, mutect2, varscan2
- MBD5 | c.4296A>T p.E1432D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101290272; called by muse, mutect2, varscan2
- MBD6 | c.1358C>A p.P453H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1224530856, COSV100851827; called by muse, mutect2, varscan2
- MBOAT2 | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100020661; called by muse, mutect2, varscan2
- MCC | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV101342742; called by muse, mutect2
- MED7 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV99644329; called by muse, mutect2, varscan2
- METTL5 | c.385T>G p.F129V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641915; called by muse, mutect2, varscan2
- MICAL2 | c.2236G>T p.G746C | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV99818024, COSV99818394; called by muse, mutect2
- MINDY4 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1562530135, COSV99519271; called by muse, mutect2, varscan2
- MLLT1 | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99398261; called by muse, mutect2, varscan2
- MMAA | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV55579960; called by muse, mutect2
- MORN5 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101055636, COSV65649026; called by muse, mutect2
- MRPL16 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs746870214, COSV55698374; called by muse, mutect2, varscan2
- MSH2 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99254570; called by muse, mutect2, varscan2
- MSH2 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.451); catalogued as rs63750821, COSV51882519; called by muse, mutect2, varscan2
- MSMO1 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99823440; called by muse, mutect2
- MSMP | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 54/379 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); catalogued as COSV65239331; called by muse, mutect2, varscan2
- MSMP | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100960380; called by muse, mutect2, varscan2
- MSRB2 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs745379676, COSV100919732; called by muse, mutect2
- MTHFD1L | c.2708T>C p.L903S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100945367; called by muse, mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MUC16 | c.34910G>T p.S11637I | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV101198641; called by muse, mutect2, varscan2
- MUC16 | c.11009C>A p.A3670E | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV101201753; called by muse, mutect2, varscan2
- MUC5B | c.4468C>A p.P1490T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.766); catalogued as COSV101500776, COSV71594151; called by muse, mutect2, varscan2
- MYB | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100214916, COSV100215177; called by muse, mutect2, varscan2
- MYBPH | c.1195A>T p.T399S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99704752; called by muse, mutect2, varscan2
- MYC | c.175C>A p.P59T (on ENST00000377970; = p.P74T on NM_002467.6) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52367409, COSV52367643, COSV52370791; called by muse, mutect2, varscan2
- MYH1 | c.2124C>G p.I708M | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99876909; called by muse, mutect2, varscan2
- MYH1 | c.361T>A p.L121M | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99876912; called by muse, mutect2, varscan2
- MYH14 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV99224178; called by muse, mutect2
- MYH4 | c.527T>A p.L176* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99702266; called by muse, mutect2
- MYH6 | c.3784C>A p.R1262S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV100676216, COSV100677005; called by muse, mutect2, varscan2
- MYH7 | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100806672; called by muse, mutect2, varscan2
- MYH8 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV101238807, COSV99063273; called by muse, mutect2, varscan2
- MYLK3 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV101189223; called by muse, mutect2
- MYO3B | c.3352G>T p.A1118S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV100511831; called by muse, mutect2, varscan2
- MYO5B | c.5347A>G p.N1783D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.123); catalogued as COSV99546268; called by muse, mutect2, varscan2
- MYO5B | c.4325C>T p.A1442V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99546270; called by muse, mutect2, varscan2
- MYO7B | c.4185G>C p.Q1395H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV101268394; called by muse, mutect2
- MYOM2 | c.4100C>T p.T1367M | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs368659851; called by muse, mutect2, varscan2
- MYRF | c.109A>C p.I37L (on ENST00000278836 / NM_001127392.3; = p.I28L on NM_013279.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV99607917; called by muse, mutect2, varscan2
- NAGK | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV99730762; called by muse, mutect2, varscan2
- NAV3 | c.4397C>A p.A1466D | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV99895794; called by muse, mutect2, varscan2
- NCDN | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100357713; called by muse, mutect2, varscan2
- NCOA2 | c.1954A>T p.M652L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200606374, COSV101476058; called by muse, mutect2, varscan2
- NCOR2 | c.2771A>G p.D924G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100657902; called by muse, mutect2, varscan2
- NDN | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100086733; called by muse, mutect2
- NDRG2 | c.892A>C p.T298P (on ENST00000298687 / NM_001354570.1; = p.T284P on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV100069168; called by muse, mutect2, varscan2
- NDRG4 | c.78del p.K27Rfs*82 (on ENST00000570248 / NM_001378344.1; = p.K59Rfs*82 on NM_020465.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as COSV50747576, COSV50749404; called by mutect2, pindel, varscan2
- NEB | c.11599G>A p.D3867N | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1283048983, COSV99428144; called by muse, mutect2
- NEUROD1 | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99717061; called by muse, mutect2
- NGEF | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs779792421, COSV99890911; called by muse, mutect2, varscan2
- NIN | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760381596, COSV99815318; called by mutect2, varscan2
- NLRP2 | c.1326G>T p.Q442H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99672441, COSV99672666; called by muse, mutect2, varscan2
- NLRP3 | c.1102A>T p.I368F | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100276670; called by muse, mutect2, varscan2
- NLRP3 | c.1789A>C p.K597Q | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV60220937; called by muse, mutect2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOCT | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99763967; called by muse, mutect2
- NOSTRIN | c.559T>C p.Y187H (on ENST00000317647 / NM_001039724.4; = p.Y109H on NM_052946.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755489701, COSV100474101; called by muse, mutect2, varscan2
- NPAP1 | c.2105C>T p.T702I | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs752619756, COSV100276217; called by muse, mutect2, varscan2
- NR2C1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100280670; called by muse, mutect2
- NR4A2 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277388; called by muse, mutect2, varscan2
- NRCAM | c.974T>A p.L325* (on ENST00000379028 / NM_001371124.1; = p.L319* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100695539; called by muse, mutect2
- NSRP1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55935215; called by muse, mutect2
- NSUN6 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99996461; called by muse, mutect2, varscan2
- NT5DC2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs779694312, COSV58739547; called by muse, mutect2, varscan2
- NTSR2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs577111587, COSV100184031; called by muse, mutect2, varscan2
- NUP205 | c.2955C>G p.I985M | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.596); catalogued as COSV99607621; called by muse, mutect2
- NUP85 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs201896656, COSV55457626; called by muse, mutect2, varscan2
- NUP93 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs150762291; called by muse, mutect2, varscan2
- OBI1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758932717, COSV56145001; called by muse, mutect2, varscan2
- OBSCN | c.6571C>G p.R2191G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV52758397, COSV99484433; called by muse, mutect2
- OLFM2 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99322059; called by muse, mutect2, varscan2
- OPTC | c.960C>G p.Y320* | Nonsense Mutation (SNP) | VAF 21/174 reads (12%) | catalogued as COSV100921842; called by muse, mutect2, varscan2
- OR10A4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV101139602; called by muse, mutect2
- OR13A1 | c.235T>G p.F79V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100981094; called by muse, mutect2, varscan2
- OR1S1 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs376704514, COSV100515492, COSV58707387; called by muse, mutect2, varscan2
- OR2A5 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs377097502, COSV101278824; called by muse, mutect2, varscan2
- OR2G3 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 57/470 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs547978827, COSV100180784; called by muse, mutect2, varscan2
- OR2G6 | c.754T>G p.Y252D | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100598321; called by muse, mutect2, varscan2
- OR2H1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.134); catalogued as COSV101009937; called by muse, mutect2, varscan2
- OR2H2 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs759258206, COSV63541036; called by muse, varscan2
- OR2T33 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58817052; called by muse, mutect2, varscan2
- OR4K15 | c.652G>A p.V218I (on ENST00000305051; = p.V194I on NM_001005486.1) | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as rs564655959, COSV100521171; called by muse, mutect2, varscan2
- OR52N2 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100396261; called by muse, mutect2, varscan2
- OR5B2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as COSV100222987; called by muse, mutect2
- OR5D13 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100686985, COSV100687071; called by muse, mutect2
- OR5F1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256694310, COSV99558936; called by muse, mutect2, varscan2
- OR5M11 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.242); catalogued as COSV101602068; called by muse, mutect2
- OR5T1 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100479236; called by muse, mutect2, varscan2
- OR6V1 | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101389563; called by muse, mutect2, varscan2
- OR7E24 | c.702C>G p.F234L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV101509689; called by muse, mutect2
- OR8H1 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100477361, COSV100477398; called by muse, mutect2
- OTOA | c.940T>G p.S314A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV99625787; called by muse, mutect2, varscan2
- OTOGL | c.3420C>A p.Y1140* (on ENST00000547103; = p.Y1131* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101509510; called by muse, mutect2, varscan2
- OTOGL | c.3451A>T p.I1151F (on ENST00000547103; = p.I1142F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101509511; called by muse, mutect2, varscan2
- OTP | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.9); catalogued as COSV100119909; called by muse, mutect2, varscan2
- OVCH1 | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100549230; called by muse, mutect2, varscan2
- P3H1 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355604; called by muse, mutect2, varscan2
- PADI3 | c.950C>G p.T317R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV100968602; called by muse, mutect2, varscan2
- PAK4 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370979504; called by muse, mutect2, varscan2
- PALB2 | c.1805A>T p.Q602L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.288); catalogued as rs864622768, COSV99848996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARP9 | c.2011G>A p.V671M | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831273; called by muse, mutect2, varscan2
- PAX5 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV63908703; called by muse, mutect2, varscan2
- PCARE | c.3631A>G p.T1211A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100527888; called by muse, mutect2, varscan2
- PCDH1 | c.3245T>C p.L1082P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746998; called by muse, mutect2, varscan2
- PCDH10 | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.04); catalogued as COSV99994565; called by muse, mutect2
- PCDH10 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994566; called by muse, mutect2, varscan2
- PCDHA2 | c.740A>T p.Y247F | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs782408299, COSV100974152; called by muse, mutect2, varscan2
- PCDHA2 | c.1547A>T p.K516M | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100974153; called by muse, varscan2
- PCDHB3 | c.638C>A p.T213N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV99166693; called by muse, mutect2, varscan2
- PCDHB7 | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as COSV99177411; called by muse, mutect2
- PCDHGA5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.248); catalogued as COSV99547223; called by muse, mutect2, varscan2
- PCDHGB4 | c.2044C>T p.L682F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs868132990, COSV99547225; called by muse, mutect2
- PCDHGC5 | c.1468A>G p.T490A | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99342405; called by muse, mutect2, varscan2
- PCM1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV61514760; called by muse, mutect2, varscan2
- PCNT | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100856041; called by muse, mutect2, varscan2
- PCSK5 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100950693; called by muse, mutect2, varscan2
- PDE11A | c.1528A>G p.R510G | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99615040, COSV99616283; called by muse, varscan2
- PDE2A | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV57814738; called by muse, mutect2, varscan2
- PFKP | c.1388G>T p.W463L | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101127542; called by muse, mutect2, varscan2
- PHF19 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100384386; called by muse, mutect2
- PIP4K2A | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100114684; called by muse, mutect2, varscan2
- PIRT | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as COSV101652686; called by muse, mutect2, varscan2
- PKD1 | c.3188C>T p.A1063V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99239069; called by muse, mutect2, varscan2
- PKD2L1 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100559457; called by muse, mutect2, varscan2
- PKHD1L1 | c.10719A>T p.R3573S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101006850; called by muse, mutect2
- PKN3 | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs373837557; called by muse, mutect2, varscan2
- PKP2 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as COSV50746069; called by muse, mutect2, varscan2
- PKP2 | c.1780A>G p.I594V | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs727503371, COSV99298504; ClinVar: uncertain significance; called by mutect2, varscan2
- PLA2G4A | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as rs1353959040, COSV100820736; called by muse, mutect2, varscan2
- PLAC8L1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100268790; called by muse, mutect2, varscan2
- PLCB4 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1312728965, COSV99595366; called by muse, mutect2, varscan2
- PLEC | c.2264T>C p.L755S (on ENST00000322810 / NM_201380.4; = p.L645S on NM_000445.5) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100519162; called by muse, mutect2, varscan2
- PLEC | c.1402G>A p.A468T (on ENST00000322810 / NM_201380.4; = p.A358T on NM_000445.5) | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs782338088; called by muse, mutect2
- PLEKHA5 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100164766; called by muse, mutect2, varscan2
- PLEKHG4 | c.2188C>A p.L730I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100431233; called by muse, mutect2
- PLIN4 | c.628G>A p.V210M (on ENST00000301286; = p.V225M on NM_001367868.2) | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs370864165; called by muse, mutect2, varscan2
- PLXNB2 | c.3335T>A p.I1112N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100834323; called by muse, mutect2, varscan2
- POC1B | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100544535; called by muse, mutect2, varscan2
- POFUT2 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100499419; called by muse, mutect2
- POGK | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as COSV63312658; called by muse, mutect2, varscan2
- POLD1 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs754917939, COSV101486926; called by muse, varscan2
- POLR2A | c.1227del p.N410Tfs*60 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as rs966918595; called by mutect2, pindel, varscan2
- POM121L12 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs746935593, COSV101374985, COSV68693220; called by muse, mutect2, varscan2
- POU4F2 | c.288+1G>A p.X96_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99850834; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.009); catalogued as rs1473237426, COSV53453717; called by muse, mutect2, varscan2
- PPARGC1B | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58527289; called by muse, mutect2, varscan2
- PPEF2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99715008; called by muse, mutect2, varscan2
- PPL | c.4265G>A p.R1422Q | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as rs771592913, COSV99278655; called by muse, mutect2, varscan2
- PPP1R3C | c.700T>C p.F234L | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99491131; called by muse, mutect2, varscan2
- PPP2R3A | c.663T>A p.D221E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV53866483, COSV99388225; called by muse, mutect2, varscan2
- PPP4R4 | c.1722G>T p.L574F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.332); catalogued as COSV100429037; called by muse, mutect2, varscan2
- PRDM15 | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99521009; called by muse, mutect2, varscan2
- PRDM16 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99578925; called by muse, mutect2, varscan2
- PRDM9 | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99691283; called by muse, mutect2, varscan2
- PRDX6 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1162142291, COSV100458573; called by muse, mutect2, varscan2
- PREX1 | c.1413G>T p.L471F | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100906824; called by muse, mutect2, varscan2
- PRG4 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100798328; called by muse, varscan2
- PRICKLE4 | c.595A>C p.S199R (on ENST00000359201; = p.S239R on NM_013397.6) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100138913; called by muse, mutect2, varscan2
- PRKAG3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs763811657, COSV52104352; called by muse, mutect2, varscan2
- PRKDC | c.4264A>G p.K1422E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100042932; called by muse, mutect2, varscan2
- PRKG2 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100020562; called by muse, mutect2, varscan2
- PRMT8 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99713702; called by muse, mutect2, varscan2
- PROSER1 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100613056, COSV61488320; called by muse, mutect2, varscan2
- PRR27 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV100748907; called by muse, mutect2, varscan2
- PRRC2C | c.4313G>T p.R1438L (on ENST00000367742; = p.R1436L on NM_015172.4) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100146093; called by muse, mutect2, varscan2
- PRSS35 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV63800755; called by muse, mutect2, varscan2
- PRSS36 | c.1093T>A p.F365I | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99191340; called by muse, mutect2, varscan2
- PRSS38 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765433110, COSV64542227; called by muse, mutect2, varscan2
- PTCD3 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 39/151 reads (26%) | catalogued as rs1004484292, COSV99606661; called by muse, mutect2, varscan2
- PTCH1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV100110036; called by muse, mutect2, varscan2
- PTEN | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs867171992, COSV64298151, COSV64304002; called by muse, varscan2
- PTOV1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs750669934, COSV55586198; called by muse, mutect2, varscan2
- PTP4A3 | c.423C>G p.I141M (on ENST00000329397; = p.I116M on NM_007079.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100267451; called by muse, mutect2
- PTPN14 | c.1707_1708insA p.Y570Ifs*131 | Frame Shift Ins (INS) | VAF 10/93 reads (11%) | catalogued as COSV100872944; called by mutect2, varscan2
- PTPN23 | c.4249G>A p.G1417R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs773663848, COSV99651065; called by muse, mutect2, varscan2
- PTPRG | c.2119T>C p.F707L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99876965; called by muse, mutect2, varscan2
- PTPRK | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949711; called by muse, mutect2
- PTPRN | c.736A>G p.R246G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV99834360; called by muse, mutect2, varscan2
- PTPRN | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99834361; called by muse, mutect2, varscan2
- PTPRN2 | c.1442C>G p.S481W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs369875860, COSV101235371; called by muse, mutect2, varscan2
- PTPRO | c.2621A>T p.Y874F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as COSV99841771; called by muse, mutect2, varscan2
- PTPRT | c.4186G>C p.E1396Q | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100630555, COSV61974242; called by muse, mutect2
- PYGO2 | c.731T>G p.F244C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV100868991; called by muse, mutect2
- QSOX1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145185695; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2141A>T p.Q714L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99770503; called by muse, mutect2, varscan2
- RAB30 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99475924; called by muse, mutect2
- RALBP1 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375010086; called by muse, mutect2, varscan2
- RASA2 | c.149T>C p.L50S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99656746; called by muse, mutect2, varscan2
- RBBP6 | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100154985; called by muse, mutect2, varscan2
- RBM23 | c.860G>A p.G287D (on ENST00000359890 / NM_001077351.2; = p.G271D on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100321529; called by muse, mutect2
- REPS1 | c.1955A>T p.H652L (on ENST00000450536 / NM_001286611.2; = p.H651L on NM_031922.4) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as COSV99239047; called by muse, mutect2, varscan2
- RESF1 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100440618; called by muse, mutect2, varscan2
- RESF1 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV100440619; called by muse, mutect2, varscan2
- RGS12 | c.2747G>T p.G916V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100123364; called by muse, mutect2, varscan2
- RGS2 | c.110+2T>C p.X37_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99343475; called by muse, mutect2
- RGS20 | c.824C>T p.A275V (on ENST00000297313 / NM_170587.4; = p.A128V on NM_003702.4) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as COSV52019998; called by muse, mutect2, varscan2
- RHBDF1 | c.1357T>C p.Y453H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99245149; called by muse, mutect2, varscan2
- RHNO1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100817085; called by muse, mutect2, varscan2
- RIMKLA | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV68909789; called by muse, mutect2, varscan2
- RIMS1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99330550; called by muse, mutect2, varscan2
- RIMS2 | c.1570G>A p.E524K (on ENST00000666250 / NM_001348490.2; = p.E332K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99199969, COSV99212417; called by muse, mutect2
- RIT1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 38/180 reads (21%) | catalogued as COSV64171916; called by muse, mutect2, varscan2
- RNASEH2A | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.216); catalogued as rs1396544058, COSV99677417; called by muse, mutect2
- RNF112 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV71327013, COSV71327094; called by muse, mutect2
- RNF213 | c.7465G>A p.A2489T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100301529; called by muse, mutect2, varscan2
- RNF43 | c.1976dup p.P660Sfs*87 | Frame Shift Ins (INS) | VAF 32/134 reads (24%) | catalogued as rs755128667; called by mutect2, varscan2
- RP1L1 | c.1835T>G p.V612G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV101223642; called by muse, mutect2, varscan2
- RPAP1 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV100427360; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL8 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV99369757, COSV99369985; called by muse, mutect2
- RPS6 | c.348del p.G117Efs*8 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as rs34590252; called by mutect2, pindel, varscan2
- RPS6KA2 | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.025); catalogued as COSV101551625; called by muse, mutect2, varscan2
- RPS6KC1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874100; called by muse, mutect2, varscan2
- RREB1 | c.4892A>G p.H1631R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100619865; called by muse, mutect2, varscan2
- RRP15 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV65118004, COSV65118038; called by muse, mutect2, varscan2
- RSBN1 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.081); catalogued as rs1468513069, COSV99793613; called by muse, mutect2, varscan2
- RTP3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56123660; called by muse, mutect2, varscan2
- RYR1 | c.6052G>A p.E2018K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.258); catalogued as COSV100617040; called by muse, mutect2
- RYR2 | c.2933C>G p.P978R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100772930; called by muse, mutect2, varscan2
- S100A12 | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV100907185; called by muse, mutect2, varscan2
- SALL1 | c.1924C>A p.L642M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV99190833; called by muse, mutect2
- SALL3 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV101610059; called by muse, mutect2, varscan2
- SALL4 | c.1079A>G p.K360R | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99409859; called by muse, mutect2
- SAMD7 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100157083; called by muse, mutect2, varscan2
- SASH1 | c.782T>C p.L261S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100821458; called by muse, mutect2, varscan2
- SASH1 | c.2408G>T p.G803V | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); catalogued as rs1184093477, COSV100821459; called by muse, mutect2, varscan2
- SCAF11 | c.3472G>A p.V1158I | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1332605327, COSV101014663; called by muse, mutect2
- SCAMP3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100226945; called by muse, mutect2, varscan2
- SCGB1D2 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99793605; called by muse, mutect2, varscan2
- SCML1 | c.530G>A p.R177H (on ENST00000380041 / NM_001037540.3; = p.R150H on NM_006746.6) | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs371840167, COSV66240948; called by muse, mutect2, varscan2
- SCN3A | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99328577; called by muse, mutect2, varscan2
- SCN9A | c.4180C>T p.L1394F (on ENST00000303354; = p.L1383F on NM_002977.3) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV100312823, COSV100314262; called by muse, mutect2
- SCUBE1 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99298684; called by mutect2, varscan2
- SCUBE1 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99298689; called by mutect2, varscan2
- SEC24D | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99756844; called by muse, mutect2
- SEC61G | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV100769292; called by muse, mutect2, varscan2
- SEL1L | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100378116, COSV60921606; called by muse, mutect2
- SEMA3F | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50028684, COSV99137982; called by muse, mutect2, varscan2
- SEMA4F | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.497); catalogued as COSV100336162; called by muse, mutect2, varscan2
- SENP7 | c.1493G>A p.C498Y | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as COSV58613681; called by muse, mutect2
- SEPTIN6 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595232, COSV100595828; called by muse, mutect2, varscan2
- SERGEF | c.1090T>C p.C364R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99787861; called by muse, mutect2, varscan2
- SERINC5 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs759732415, COSV101549141; called by mutect2, varscan2
718 further variants in this file (347 protein-altering or splice-affecting, 340 silent, 31 other) are not listed here.
